MMRF case MMRF_1502 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d59c3a6f-f039-4d9e-87eb-804e4a786946

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,383 days); ISS stage: III; Days to last known disease status: 1,331 days (3.6 years); Days to last follow up: 1,331 days (3.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 47 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days; Days to treatment end: 218 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 219 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 368 days (1.0 years); Days to treatment end: 764 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 812 days (2.2 years); Days to treatment end: 812 days (2.2 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 829 days (2.3 years); Days to treatment end: 898 days (2.5 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,130 days (3.1 years); Days to treatment end: 1,311 days (3.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Daratumumab + Dexamethasone + Pomalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,346 days (3.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 3): M Protein 6.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.047 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.46 mg/dL; Immunoglobulin G 0.91 g/L; Immunoglobulin A 56.6 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 13.6 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 27 g/L; Total Protein 11.6 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 1.44 mg/dL.
- Day 93 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.047 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 1.27 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 3.52 mmol/L.
- Day 163 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.074 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.764 mg/dL; Immunoglobulin G 1.61 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 385 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.24 mmol/L.
- Day 289 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.042 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.042 mg/dL; Immunoglobulin G 2.12 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.12 g/dL; Glucose 4.95 mmol/L.
- Day 702 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.684 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.502 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 314 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 792 (ECOG 0): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.084 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 3.15 g/L; Immunoglobulin A 12 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.8 g/dL; Glucose 5.01 mmol/L.
- Day 912 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.853 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.922 mg/dL; Immunoglobulin G 3.22 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 364 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 1,149 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.869 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.806 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 1,254 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.086 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.02 mmol/L.
- Day 1,331 (ECOG 0): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.105 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.843 mg/dL; Immunoglobulin G 2.32 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 8 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.

Other clinical attributes
- Day -3: Weight: 53 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1502_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1502_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
